Somatic mutation profile of tumor specimen BA2090D (aliquot aq-BA2090D) from BEATAML1.0 case 2414, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,445 days).
Specimen BA2090D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef355a41-9174-4d9e-a9e9-89f3b8f3b023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2572D (Solid Tissue Normal), aliquot aq-BA2572D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0c0d871-53a4-48f0-8462-b92128eb9ea1

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGFBP3 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.048); called by muse, mutect2
- PLEKHG3 | c.1171C>A p.Q391K (on ENST00000394691; = p.Q447K on NM_001308147.2) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2
- WDR1 | c.371G>T p.R124M | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZNF236 | c.4811C>G p.S1604C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- AC098582.1 | c.201C>A p.G67= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- ZNF717 | c.480T>C p.N160= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1015141252, COSV68863597; called by muse, mutect2
